Gene-level copy-number profile of tumor specimen TCGA-AR-A24U-01A from TCGA case TCGA-AR-A24U, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 48.0 years (17,523 days).
Specimen TCGA-AR-A24U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.6c84f85f-2dd5-452e-8658-a7844f7143ed.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A24U-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/798324eb-d6b7-4f80-b5ec-f7db88259af6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,906; copy number 2: 41,090; copy number 3: 6,069; copy number 4: 1,215; copy number 5: 536; copy number 6: 194; copy number 7: 350; copy number 8: 109; copy number 9: 81; copy number 10: 111; copy number 11: 55; copy number 14: 18; copy number 15: 53; copy number 18: 32.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A24U-01A-11D-A166-01): tumor purity 0.31, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,535 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:76,491,200–134,881,899, 841 genes, copy number 5–10 (within-gene range 4–10) (broad region; genes not listed).
- chr10:64,620,374–65,880,289, 10 genes, copy number 11 (within-gene range 2–11): RPL17P35, CYP2C61P, ANXA2P3, LINC02671, NEK4P3, AL513321.2, MYL6P3, AL513321.1, AL592466.1, LINC01515.
- chr10:69,123,512–74,121,363, 151 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr10:74,551,392–78,178,186, 62 genes, copy number 8 (broad region; genes not listed).
- chr10:78,288,059–78,290,565, 1 gene, copy number 10: AC010163.3.
- chr10:78,696,062–79,584,877, 15 genes, copy number 10: AC016820.1, ZMIZ1-AS1, AL356753.1, ZMIZ1, PPIF, ZCCHC24, AL133481.1, TPRX1P1, AL133481.3, AL133481.2, EIF5AL1, BX248123.1, RPS12P18, SFTPA2, MBL3P.
- chr17:38,351,844–40,061,215, 81 genes, copy number 6–18 (within-gene range 2–18) (broad region; genes not listed).
- chr17:47,409,322–49,369,998, 102 genes, copy number 5–15 (within-gene range 1–15) (broad region; genes not listed).
- chr17:49,375,380–49,380,094, 1 gene, copy number 5: AC091180.4.
- chr17:50,560,715–50,627,474, 1 gene, copy number 14 (within-gene range 2–14): CACNA1G.
- chr17:50,627,032–50,910,774, 17 genes, copy number 14: AC004590.1, ABCC3, ANKRD40, AC005921.2, Y_RNA, LUC7L3, AC005921.3, ANKRD40CL, MIR8059, AC005921.4, AC005921.1, WFIKKN2, AC091062.1, RPL5P33, TOB1, TOB1-AS1, AC005920.4.
- chr17:60,392,429–60,666,280, 10 genes, copy number 7–10 (within-gene range 1–10): C17orf64, RPL12P38, APPBP2, AC011921.3, AC011921.1, AC011921.2, LINC01999, RPSAP66, PPM1D, RNU6-623P.
- chr17:60,696,313–60,811,462, 4 genes, copy number 7: RN7SL606P, AC110602.1, Y_RNA, KRT18P61.
- chr17:64,308,316–65,561,648, 45 genes, copy number 11: RPL31P57, PECAM1, Y_RNA, AC234063.1, MILR1, POLG2, ATP5MFP4, DDX5, MIR3064, MIR5047, CEP95, SMURF2, AC009994.1, MICOS10P2, ARHGAP27P1-BPTFP1-KPNA2P3, KPNA2P3, AC132812.1, BPTFP1, AC103810.3, PLEKHM1P1, MIR6080, MIR4315-2, RNU7-115P, AC103810.9, LRRC37A3, RN7SL404P, AC103810.6, AC103810.7, AC103810.2, AC103810.5, RDM1P4, AC103810.1, AC103810.4, AC037487.4, AC103810.8, AC037487.1, AC037487.3, SLC16A6P1, AMZ2P1, GNA13, AC037487.2, RGS9, AC060771.1, LINC02563, AXIN2.
- chr17:74,203,582–75,031,186, 39 genes, copy number 9: RPL38, MGC16275, TTYH2, AC100786.1, DNAI2, AC103809.1, KIF19, BTBD17, GPR142, RNA5SP448, GPRC5C, CD300A, CD300LB, CD300C, AC079325.1, CD300H, CD300LD, C17orf77, AC064805.1, CD300E, AC064805.2, RAB37, CD300LF, AC016888.1, MIR3615, SLC9A3R1, NAT9, TMEM104, GRIN2C, FDXR, FADS6, USH1G, OTOP2, OTOP3, HID1, HID1-AS1, CDR2L, MRPL58, RNU6-362P.
- chr17:75,038,863–75,046,985, 2 genes, copy number 9: ATP5PD, RN7SL573P.
- chr19:27,638,483–31,147,981, 70 genes, copy number 5 (broad region; genes not listed).
- chr19:31,167,457–31,225,143, 1 gene, copy number 5 (within-gene range 2–5): LINC01791.
- chr21:31,118,416–33,479,974, 58 genes, copy number 5 (within-gene range 3–5): TIAM1, AP000248.1, AP000563.1, AP000251.1, FBXW11P1, AP000253.1, SOD1, AP000254.1, AP000254.2, SCAF4, HMGN1P2, AP000255.1, TPT1P1, HUNK, HUNK-AS1, LINC00159, AP000265.1, MIS18A, MIS18A-AS1, MRAP, MRAP-AS1, URB1, SNORA80A, URB1-AS1, CFAP298-TCP10L, EVA1C, EXOSC3P1, TCP10L, AP000272.1, RNA5SP490, CFAP298, OR7E23P, AP000275.1, SYNJ1, PAXBP1-AS1, PAXBP1, C21orf62-AS1, AP000280.2, C21orf62, AP000281.1, SNORA70, AP000281.2, AP000282.1, LINC01690, OLIG2, LINC00945, OLIG1, AP000289.1, AP000290.1, LINC01548, IFNAR2, AP000295.1, IL10RB-DT, IL10RB, IFNAR1, USF1P1, IFNGR2, TMEM50B.
- chr22:47,345,569–49,266,080, 24 genes, copy number 5: Z82186.1, LINC01644, LINC00898, AL117329.1, AL117329.2, FP325330.3, FP325330.1, FP325330.2, BX284656.2, BX284656.1, AL008720.1, MIR3201, AL008720.2, Z72006.1, Z82249.1, Z84468.2, TAFA5, Z84468.1, MIR4535, LINC01310, AL078622.1, Z82202.2, RPL35P8, Z82202.1.

Autosomal genes at a single copy (total copy number 1): 8,396. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
